Somatic mutation profile of tumor specimen TCGA-04-1367-01A (aliquot TCGA-04-1367-01A-01W-0492-08) from TCGA case TCGA-04-1367, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 50.9 years (18,577 days).
Specimen TCGA-04-1367-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) e4a4b96b-a541-4461-bf5b-6979918d3d81.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-04-1367-10A (Blood Derived Normal), aliquot TCGA-04-1367-10A-01W-0492-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f2bc311e-0904-4678-8dbd-e39631f3186a

The open-access MAF lists 118 somatic variants for this specimen: 91 protein-altering or splice-affecting, 23 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 76, Silent 23, Frame Shift Del 6, Nonsense Mutation 5, Intron 2, Splice Site 1, In Frame Del 1, Nonstop Mutation 1, Frame Shift Ins 1, 3'Flank 1, 5'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- F8 | c.5143C>T p.R1715* | Nonsense Mutation (SNP) | VAF 180/206 reads (87%) | catalogued as rs137852439, CM900094, CM920258, COSV64271015; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NF1 | c.334C>T p.Q112* | Nonsense Mutation (SNP) | VAF 269/352 reads (76%) | catalogued as rs1555606061, CM1311451, COSV62224041; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.722C>T p.S241F | Missense Mutation (SNP) | VAF 598/712 reads (84%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934573, CM1212186, CM920673, COSV52661688, COSV52662386, COSV52713934, COSV52760886; ClinVar: likely pathogenic / pathogenic; called by muse, mutect2, varscan2
- ACAD11 | c.13G>T p.A5S | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.197); catalogued as COSV53894061; called by muse, varscan2
- ADAM19 | c.1047C>A p.H349Q | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57440718; called by muse, varscan2
- AGT | c.510C>A p.N170K | Missense Mutation (SNP) | VAF 13/252 reads (5%) | SIFT tolerated (0.07); PolyPhen benign (0.342); catalogued as COSV100794221; called by muse, mutect2
- AMER2 | c.71G>T p.G24V | Missense Mutation (SNP) | VAF 6/10 reads (60%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.865); catalogued as COSV63440674; called by muse, mutect2, varscan2
- ANKRD11 | c.4553C>G p.S1518C | Missense Mutation (SNP) | VAF 35/259 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as rs1298767812, COSV56373892; called by muse, mutect2, varscan2
- AP5S1 | c.242C>T p.P81L | Missense Mutation (SNP) | VAF 16/43 reads (37%) | SIFT tolerated (0.24); PolyPhen benign (0.003); catalogued as rs748789852, COSV55693684, COSV99853286; called by muse, mutect2, varscan2
- ARL13A | c.689G>C p.R230T | Missense Mutation (SNP) | VAF 25/34 reads (74%) | SIFT deleterious (0); PolyPhen benign (0.435); catalogued as rs1483191015, COSV65880394; called by muse, mutect2, varscan2
- ATP11A | c.611A>G p.E204G | Missense Mutation (SNP) | VAF 50/241 reads (21%) | SIFT tolerated (0.36); PolyPhen benign (0.158); catalogued as rs575639303, COSV52126344; called by muse, mutect2, varscan2
- ATXN10 | c.380C>G p.S127C | Missense Mutation (SNP) | VAF 77/100 reads (77%) | SIFT tolerated (0.2); PolyPhen benign (0.401); catalogued as COSV53294756; called by muse, mutect2, varscan2
- B3GAT2 | c.829C>G p.L277V | Missense Mutation (SNP) | VAF 239/327 reads (73%) | SIFT deleterious (0); PolyPhen possibly damaging (0.907); catalogued as COSV57645617; called by muse, mutect2, varscan2
- C4orf50 | c.340C>A p.Q114K (on ENST00000324058; = p.Q1346K on NM_001364689.1 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 23/178 reads (13%) | SIFT tolerated (0.34); PolyPhen benign (0.124); catalogued as COSV60690956; called by muse, mutect2, varscan2
- CACNA2D3 | c.3233T>G p.V1078G | Missense Mutation (SNP) | VAF 118/2012 reads (6%) | SIFT tolerated (0.33); PolyPhen benign (0.007); catalogued as COSV99870789; called by muse, mutect2
- CCDC6 | c.650T>C p.L217P | Missense Mutation (SNP) | VAF 175/458 reads (38%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV54060874; called by muse, mutect2, varscan2
- CCDC88C | c.4273C>T p.R1425C | Missense Mutation (SNP) | VAF 39/231 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as rs778992254, COSV58660622; called by muse, mutect2, varscan2
- CDC7 | c.1597G>C p.E533Q | Missense Mutation (SNP) | VAF 124/940 reads (13%) | SIFT tolerated (0.11); PolyPhen benign (0.054); catalogued as COSV52313017; called by muse, mutect2, varscan2
- CDHR3 | c.1320C>G p.Y440* | Nonsense Mutation (SNP) | VAF 8/64 reads (13%) | catalogued as COSV58422576; called by muse, mutect2, varscan2
- CDK1 | c.217G>C p.D73H | Missense Mutation (SNP) | VAF 151/410 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV57350491; called by muse, mutect2, varscan2
- CES3 | c.977A>G p.K326R | Missense Mutation (SNP) | VAF 336/1468 reads (23%) | SIFT tolerated (0.22); PolyPhen benign (0.038); catalogued as rs758144938, COSV57595723; called by mutect2, varscan2
- CIC | c.110G>C p.W37S | Missense Mutation (SNP) | VAF 64/76 reads (84%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.601); catalogued as COSV50678378; called by muse, mutect2, varscan2
- CLIC6 | c.1550A>T p.D517V (on ENST00000360731 / NM_001317009.2; = p.D499V on NM_053277.3) | Missense Mutation (SNP) | VAF 140/401 reads (35%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.999); catalogued as COSV62449846; called by muse, mutect2, varscan2
- COL6A3 | c.2364G>T p.Q788H | Missense Mutation (SNP) | VAF 20/123 reads (16%) | SIFT tolerated (0.06); PolyPhen benign (0.018); catalogued as COSV55113238; called by muse, mutect2, varscan2
- COX15 | c.343G>A p.E115K | Missense Mutation (SNP) | VAF 189/281 reads (67%) | SIFT tolerated (0.3); PolyPhen benign (0.038); catalogued as COSV50013460; called by muse, mutect2, varscan2
- CTSD | c.1147T>A p.W383R | Missense Mutation (SNP) | VAF 4/50 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99362241; called by muse, mutect2
- CUX1 | c.41A>T p.D14V (on ENST00000292535 / NM_181552.4; = p.D25V on NM_001913.5) | Missense Mutation (SNP) | VAF 302/773 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.637); catalogued as COSV52918285; called by muse, mutect2, varscan2
- CUX2 | c.3262C>T p.R1088W | Missense Mutation (SNP) | VAF 37/111 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as rs1180503290, COSV55624594; called by muse, mutect2, varscan2
- CYTIP | c.742A>T p.S248C | Missense Mutation (SNP) | VAF 44/118 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV51636528; called by muse, mutect2, varscan2
- DEPDC7 | c.345del p.F116Lfs*29 (on ENST00000241051 / NM_001077242.2; = p.F107Lfs*29 on NM_139160.2) | Frame Shift Del (DEL) | VAF 8/36 reads (22%) | catalogued as COSV53805775; called by mutect2, pindel, varscan2
- DLG1 | c.2212A>G p.K738E (on ENST00000419354 / NM_001290983.1; = p.K760E on NM_004087.2) | Missense Mutation (SNP) | VAF 95/194 reads (49%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.629); catalogued as COSV58392675; called by muse, mutect2, varscan2
- DNAH3 | c.6736A>G p.M2246V | Missense Mutation (SNP) | VAF 20/74 reads (27%) | SIFT tolerated (0.5); PolyPhen benign (0.007); catalogued as COSV54556958; called by muse, mutect2, varscan2
- DNAJA4 | c.27C>A p.D9E (on ENST00000343789; = p.D38E on NM_018602.3) | Missense Mutation (SNP) | VAF 22/30 reads (73%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.571); catalogued as COSV59427436; called by muse, mutect2, varscan2
- DSCAM | c.3994A>T p.I1332F | Missense Mutation (SNP) | VAF 98/225 reads (44%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.502); catalogued as COSV68037803; called by muse, mutect2, varscan2
- ELP1 | c.1380C>A p.D460E | Missense Mutation (SNP) | VAF 49/111 reads (44%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.976); catalogued as COSV65897921, COSV65900301; called by muse, mutect2, varscan2
- EPHA3 | c.1691T>A p.I564N | Missense Mutation (SNP) | VAF 299/697 reads (43%) | SIFT tolerated (0.2); PolyPhen benign (0.034); catalogued as COSV60730527; called by muse, mutect2, varscan2
- ESPN | c.614A>G p.D205G | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV64705547; called by muse, mutect2, varscan2
- ESX1 | c.1116G>T p.M372I | Missense Mutation (SNP) | VAF 56/72 reads (78%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.014); catalogued as COSV101006398; called by muse, varscan2
- FAM83A | c.326C>T p.A109V | Missense Mutation (SNP) | VAF 153/310 reads (49%) | SIFT tolerated (0.62); PolyPhen benign (0.012); catalogued as COSV52688589; called by muse, mutect2, varscan2
- FER1L6 | c.4675G>T p.D1559Y | Missense Mutation (SNP) | VAF 81/236 reads (34%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); catalogued as COSV67549426, COSV67553197; called by muse, mutect2, varscan2
- GGA1 | c.1086G>A p.M362I | Missense Mutation (SNP) | VAF 93/147 reads (63%) | SIFT tolerated (0.06); PolyPhen benign (0.027); catalogued as rs1425433489, COSV57332062; called by muse, mutect2, varscan2
- GJA10 | c.964T>A p.W322R | Missense Mutation (SNP) | VAF 7/93 reads (8%) | SIFT tolerated (0.19); PolyPhen benign (0.007); catalogued as COSV101005289; called by muse, mutect2
- HECTD1 | c.5679C>G p.C1893W | Missense Mutation (SNP) | VAF 37/79 reads (47%) | SIFT tolerated, low confidence (0.15); PolyPhen probably damaging (0.971); catalogued as COSV67949572; called by muse, mutect2, varscan2
- HEPHL1 | c.2048_2055del p.A683Gfs*12 | Frame Shift Del (DEL) | VAF 31/76 reads (41%) | catalogued as COSV59897236; called by mutect2, pindel, varscan2
- HERPUD2 | c.854G>A p.R285Q | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as rs1341275029, COSV60947739; called by muse, mutect2, varscan2
- HOATZ | c.62dup p.L23Ifs*16 | Frame Shift Ins (INS) | VAF 9/76 reads (12%) | catalogued as rs570525399; called by mutect2, pindel, varscan2
- HOXD10 | c.637G>A p.V213I | Missense Mutation (SNP) | VAF 7/24 reads (29%) | SIFT tolerated (0.23); PolyPhen benign (0.005); catalogued as COSV50896390; called by muse, mutect2, varscan2
- INSC | c.14C>T p.P5L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.001); catalogued as rs749121451, COSV65413568; called by muse, mutect2, varscan2
- IQGAP2 | c.343C>T p.Q115* | Nonsense Mutation (SNP) | VAF 177/216 reads (82%) | catalogued as COSV57184346; called by muse, mutect2, varscan2
- IRS1 | c.3461G>T p.G1154V | Missense Mutation (SNP) | VAF 15/105 reads (14%) | SIFT tolerated (0.12); PolyPhen benign (0.053); catalogued as COSV59340817; called by muse, mutect2, varscan2
- ISX | c.637C>A p.P213T | Missense Mutation (SNP) | VAF 407/557 reads (73%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.476); catalogued as COSV58088584; called by muse, mutect2, varscan2
- ITGA10 | c.1562G>A p.R521H | Missense Mutation (SNP) | VAF 967/2244 reads (43%) | SIFT deleterious (0.02); PolyPhen benign (0.425); catalogued as rs928166197, COSV65199505; called by muse, mutect2, varscan2
- ITGB2 | c.898G>C p.D300H | Missense Mutation (SNP) | VAF 63/177 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV56614698; called by muse, mutect2, varscan2
- KIRREL3 | c.1010T>A p.M337K | Missense Mutation (SNP) | VAF 9/37 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.216); catalogued as rs1330065818, COSV73109700; called by muse, mutect2, varscan2
- LRP5 | c.1372C>G p.L458V | Missense Mutation (SNP) | VAF 103/170 reads (61%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.649); catalogued as COSV53724679; called by muse, mutect2, varscan2
- LRRC31 | c.371A>G p.N124S | Missense Mutation (SNP) | VAF 99/297 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV52983364; called by muse, mutect2, varscan2
- MAN1B1 | c.350A>T p.E117V | Missense Mutation (SNP) | VAF 15/122 reads (12%) | SIFT deleterious (0.04); PolyPhen benign (0.153); catalogued as COSV64307119; called by muse, mutect2
- MINDY1 | c.1121C>T p.P374L | Missense Mutation (SNP) | VAF 160/389 reads (41%) | SIFT deleterious (0); PolyPhen benign (0.007); catalogued as COSV56501350; called by muse, mutect2, varscan2
- MUC17 | c.8575G>A p.V2859M | Missense Mutation (SNP) | VAF 171/375 reads (46%) | SIFT tolerated (1); PolyPhen benign (0.366); catalogued as rs373142874, COSV60296515; called by muse, mutect2, varscan2
- MYBL1 | c.2147A>G p.E716G | Missense Mutation (SNP) | VAF 7/14 reads (50%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); catalogued as COSV72919266; called by muse, mutect2, varscan2
- MYO3A | c.4412G>C p.R1471P | Missense Mutation (SNP) | VAF 32/868 reads (4%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.222); catalogued as COSV56347299, COSV99778536; called by muse, mutect2
- NPHP1 | c.818T>G p.I273R | Missense Mutation (SNP) | VAF 115/304 reads (38%) | SIFT tolerated, low confidence (0.15); PolyPhen benign (0); catalogued as COSV57212265; called by muse, mutect2, varscan2
- NR2F2 | c.325A>T p.R109W | Missense Mutation (SNP) | VAF 102/123 reads (83%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67684228; called by muse, mutect2, varscan2
- NRCAM | c.2116A>G p.T706A (on ENST00000379028 / NM_001371124.1; = p.T690A on NM_005010.4 and 21 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 212/369 reads (57%) | SIFT deleterious (0); PolyPhen benign (0.017); catalogued as COSV61050922; called by muse, mutect2, varscan2
- OGDHL | c.1080C>G p.N360K | Missense Mutation (SNP) | VAF 36/674 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100934210; called by muse, mutect2
- OPCML | c.461C>T p.T154I | Missense Mutation (SNP) | VAF 49/1485 reads (3%) | SIFT deleterious (0); PolyPhen benign (0.217); catalogued as COSV59401156; called by muse, mutect2
- PEG3 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 280/588 reads (48%) | SIFT deleterious (0); PolyPhen benign (0.005); catalogued as rs750191135, COSV55624847; called by muse, mutect2, varscan2
- PRF1 | c.1668A>T p.*556Cext*3 | Nonstop Mutation (SNP) | VAF 46/104 reads (44%) | catalogued as COSV64615998; called by muse, mutect2, varscan2
- PRSS21 | c.722C>G p.P241R | Missense Mutation (SNP) | VAF 74/201 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV50052434; called by muse, mutect2, varscan2
- PTPN21 | c.2254G>A p.A752T | Missense Mutation (SNP) | VAF 5/17 reads (29%) | SIFT tolerated, low confidence (0.6); PolyPhen benign (0); catalogued as COSV100161550; called by muse, mutect2, varscan2
- PTPRC | c.385G>C p.G129R | Missense Mutation (SNP) | VAF 383/961 reads (40%) | SIFT deleterious (0.01); PolyPhen benign (0.431); catalogued as COSV100722169, COSV61413686; called by muse, mutect2, varscan2
- SCRN1 | c.721A>T p.S241C | Missense Mutation (SNP) | VAF 60/146 reads (41%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV54134781; called by muse, mutect2, varscan2
- SECISBP2 | c.330G>C p.Q110H | Missense Mutation (SNP) | VAF 216/491 reads (44%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV60530403; called by muse, mutect2, varscan2
- SIGLEC11 | c.239C>G p.P80R | Missense Mutation (SNP) | VAF 45/123 reads (37%) | SIFT tolerated (0.23); PolyPhen benign (0.158); catalogued as rs769319286, COSV101389105, COSV70222203; called by muse, mutect2, varscan2
- SLC38A3 | c.1414C>A p.L472M | Missense Mutation (SNP) | VAF 134/382 reads (35%) | SIFT tolerated (0.15); PolyPhen benign (0.213); catalogued as COSV68844204; called by muse, mutect2, varscan2
- SLC5A11 | c.665G>T p.S222I | Missense Mutation (SNP) | VAF 252/663 reads (38%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.973); catalogued as COSV61743904; called by muse, mutect2, varscan2
- SMC2 | c.1940C>A p.T647N | Missense Mutation (SNP) | VAF 17/498 reads (3%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.86); catalogued as COSV99658462; called by muse, mutect2
- SUPV3L1 | c.742G>T p.G248C | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV62846520; called by muse, mutect2
- SYNPO2L | c.2302C>G p.R768G (on ENST00000394810 / NM_001114133.3; = p.R544G on NM_024875.5) | Missense Mutation (SNP) | VAF 161/364 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV65739303; called by muse, mutect2, varscan2
- TAS2R20 | c.670C>T p.H224Y | Missense Mutation (SNP) | VAF 48/654 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1316655881, COSV101114200; called by muse, mutect2
- TAS2R50 | c.34C>G p.L12V | Missense Mutation (SNP) | VAF 8/19 reads (42%) | SIFT deleterious (0.04); PolyPhen benign (0.19); catalogued as COSV67852975, COSV67863268; called by mutect2, varscan2
- TXNL4B | c.345G>T p.L115F | Missense Mutation (SNP) | VAF 28/77 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.965); catalogued as COSV51702896, COSV51703623; called by muse, mutect2, varscan2
- UGT1A3 | c.772C>T p.R258* | Nonsense Mutation (SNP) | VAF 648/1624 reads (40%) | catalogued as rs756538337, COSV100529668; called by muse, mutect2, varscan2
- USF3 | c.553C>G p.P185A | Missense Mutation (SNP) | VAF 139/339 reads (41%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV57078013; called by muse, mutect2, varscan2
- VPS39 | c.406A>G p.M136V (on ENST00000348544 / NM_001301138.2; = p.M125V on NM_015289.5) | Missense Mutation (SNP) | VAF 214/454 reads (47%) | SIFT tolerated (0.05); PolyPhen benign (0.003); catalogued as COSV58790491, COSV58793937; called by muse, mutect2, varscan2
- AGAP3 | c.2248_2286del p.G750_L762del (on ENST00000622464; = p.G786_L798del on NM_031946.7 and 1 other RefSeq transcript) | In Frame Del (DEL) | VAF 64/266 reads (24%) | called by mutect2, pindel
- CDYL | c.1129_1150del p.S377Pfs*29 (on ENST00000328908 / NM_001368125.1; = p.S323Pfs*29 on NM_004824.4 and 1 other RefSeq transcript) | Frame Shift Del (DEL) | VAF 22/32 reads (69%) | called by mutect2, pindel, varscan2
- DHX9 | c.477+1_477+15del p.X159_splice | Splice Site (DEL) | VAF 22/60 reads (37%) | called by mutect2, pindel, varscan2
- KNTC1 | c.2490_2508del p.K831Tfs*3 | Frame Shift Del (DEL) | VAF 20/76 reads (26%) | called by mutect2, pindel, varscan2
- KRT82 | c.551_563del p.S184* | Frame Shift Del (DEL) | VAF 83/202 reads (41%) | called by mutect2, pindel, varscan2
- SEC16B | c.1004_1014del p.D335Gfs*18 | Frame Shift Del (DEL) | VAF 13/34 reads (38%) | called by mutect2, pindel, varscan2
- ADAM19 | c.1161C>T p.C387= | Silent (SNP) | VAF 314/559 reads (56%) | catalogued as rs1223441705, COSV99976247; called by muse, varscan2
- APCS | c.399G>A p.L133= | Silent (SNP) | VAF 45/119 reads (38%) | catalogued as COSV54819445; called by muse, mutect2, varscan2
- ARHGAP21 | c.3675C>G p.S1225= | Silent (SNP) | VAF 13/56 reads (23%) | catalogued as COSV100256309, COSV57611902; called by muse, mutect2, varscan2
- BIRC6 | c.2248C>A p.R750= | Silent (SNP) | VAF 66/1014 reads (7%) | catalogued as COSV101427911; called by muse, mutect2
- CELSR3 | c.2691G>T p.L897= | Silent (SNP) | VAF 43/95 reads (45%) | catalogued as COSV51169993; called by muse, mutect2, varscan2
- DISP2 | c.3222C>A p.G1074= | Silent (SNP) | VAF 22/50 reads (44%) | catalogued as COSV51146657; called by muse, mutect2, varscan2
- DUOX1 | c.3351C>G p.L1117= | Silent (SNP) | VAF 108/160 reads (68%) | catalogued as COSV58485671, COSV58487098; called by muse, mutect2, varscan2
- EEA1 | c.2949A>G p.K983= | Silent (SNP) | VAF 24/71 reads (34%) | catalogued as COSV59290482; called by muse, mutect2, varscan2
- FASTKD1 | c.2160G>A p.S720= | Silent (SNP) | VAF 86/233 reads (37%) | catalogued as rs372027328; called by muse, mutect2, varscan2
- FKBP15 | c.1371C>G p.A457= | Silent (SNP) | VAF 88/230 reads (38%) | catalogued as COSV53040248; called by muse, mutect2, varscan2
- GNL2 | c.1281C>T p.F427= | Silent (SNP) | VAF 209/488 reads (43%) | catalogued as COSV66081876; called by muse, mutect2, varscan2
- GRIA1 | c.1020T>G p.A340= | Silent (SNP) | VAF 33/144 reads (23%) | catalogued as COSV99598365; called by muse, mutect2, varscan2
- KNTC1 | c.2208C>A p.I736= | Silent (SNP) | VAF 98/256 reads (38%) | catalogued as COSV61085010; called by muse, mutect2, varscan2
- MYOM1 | c.4797C>T p.D1599= | Silent (SNP) | VAF 10/115 reads (9%) | catalogued as COSV99865443; called by muse, mutect2
- PGBD5 | c.834C>A p.T278= (on ENST00000525115; = p.T347= on NM_001258311.2) | Silent (SNP) | VAF 19/688 reads (3%) | catalogued as COSV100358392; called by muse, mutect2
- PSG1 | c.705C>T p.L235= | Silent (SNP) | VAF 107/1752 reads (6%) | catalogued as rs909550947, COSV99738838; called by muse, mutect2
- PXDNL | c.1885C>A p.R629= | Silent (SNP) | VAF 23/46 reads (50%) | catalogued as COSV100681695; called by muse, mutect2, varscan2
- SDHAF2 | c.48G>T p.L16= | Silent (SNP) | VAF 279/541 reads (52%) | catalogued as COSV57100339; called by muse, mutect2, varscan2
- SMPDL3B | c.555G>T p.G185= | Silent (SNP) | VAF 155/238 reads (65%) | catalogued as COSV65871686; called by muse, mutect2, varscan2
- TANC1 | c.1980G>A p.L660= | Silent (SNP) | VAF 104/207 reads (50%) | catalogued as COSV55098650; called by muse, mutect2, varscan2
- TNXB | c.4902G>A p.S1634= (on ENST00000647633; = p.S1387= on NM_019105.8 and 1 other RefSeq transcript) | Silent (SNP) | VAF 290/360 reads (81%) | catalogued as rs746110766, COSV64472540; called by muse, mutect2, varscan2
- TRIL | c.532T>C p.L178= | Silent (SNP) | VAF 16/41 reads (39%) | catalogued as rs748900559, COSV59868143; called by muse, mutect2, varscan2
- ZNF503 | c.1872A>C p.G624= | Silent (SNP) | VAF 5/18 reads (28%) | catalogued as COSV65307929; called by muse, mutect2, varscan2
- GNA12 | c.526-29239G>A | Intron (SNP) | VAF 7/22 reads (32%) | catalogued as rs561225294, COSV51743003; called by muse, varscan2
- MARCHF1 | c.-322-85474G>A | Intron (SNP) | VAF 22/25 reads (88%) | catalogued as COSV72283505, COSV72283812; called by muse, mutect2, varscan2
- PPP1R1A | chr12:54577531 G>T | 3'Flank (SNP) | VAF 594/1522 reads (39%) | catalogued as COSV99226286; called by mutect2, varscan2
- RNF185 | c.-2G>T | 5'UTR (SNP) | VAF 63/85 reads (74%) | catalogued as COSV56735844; called by muse, mutect2, varscan2
